Somatic mutation profile of tumor specimen TCGA-EJ-8472-01A (aliquot TCGA-EJ-8472-01A-11D-2395-08) from TCGA case TCGA-EJ-8472, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.3 years (23,104 days).
Specimen TCGA-EJ-8472-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d93681c-0753-4708-aaf6-dedc7843aa79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-8472-10A (Blood Derived Normal), aliquot TCGA-EJ-8472-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31ce9a43-0eb3-4a2d-b608-513b5397bd91

The open-access MAF lists 50 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Nonsense Mutation 3, RNA 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF1A | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs672601365, CM150181, COSV57488467; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 51/131 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS15 | c.1736T>C p.F579S | Missense Mutation (SNP) | VAF 109/371 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54505257; called by muse, mutect2, varscan2
- ARFGEF1 | c.4811C>T p.S1604F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV51608061; called by muse, mutect2, varscan2
- ARL2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV55861245; called by muse, mutect2, varscan2
- ARNT | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs587670365, COSV62230627; called by muse, mutect2, varscan2
- C3orf62 | c.8A>G p.Y3C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV55536904; called by muse, mutect2, varscan2
- CAMK1G | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1349002035, COSV50520946; called by muse, mutect2, varscan2
- CD248 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs750979307, COSV60936416; called by muse, mutect2, varscan2
- CNOT6L | c.1526C>T p.P509L (on ENST00000504123 / NM_001286790.2; = p.P504L on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/316 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as rs377549782, COSV53699321; called by muse, mutect2, varscan2
- COG6 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV62995901; called by muse, mutect2, varscan2
- CYP2C8 | c.331G>T p.G111* | Nonsense Mutation (SNP) | VAF 22/217 reads (10%) | catalogued as COSV64877069; called by mutect2, varscan2
- CYP2F1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 68/191 reads (36%) | catalogued as rs1349532357, COSV58527253; called by muse, mutect2, varscan2
- DEGS2 | c.905T>C p.F302S | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59784299; called by muse, mutect2, varscan2
- ERMARD | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as rs753334453, COSV64648055; called by muse, mutect2, varscan2
- FEM1A | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774638617, COSV54163770; called by muse, mutect2, varscan2
- GCN1 | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV56107571; called by muse, mutect2, varscan2
- GPR87 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.867); catalogued as COSV53463011; called by muse, mutect2, varscan2
- HFM1 | c.1741G>C p.D581H | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV54026713; called by muse, mutect2, varscan2
- HPS6 | c.1307A>C p.Q436P | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV54625590; called by muse, mutect2, varscan2
- HSPA1L | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV65149027; called by muse, mutect2, varscan2
- HTRA4 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as COSV56758921; called by muse, mutect2, varscan2
- IFNA16 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 209/502 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775275527, COSV66510028; called by muse, mutect2, varscan2
- MEF2A | c.815G>A p.R272Q (on ENST00000557942 / NM_001319206.2; = p.R274Q on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57532928; called by muse, mutect2, varscan2
- MEGF8 | c.5676C>G p.C1892W (on ENST00000251268 / NM_001271938.2; = p.C1825W on NM_001410.3) | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52084062; called by muse, mutect2, varscan2
- MUC5B | c.6565C>A p.P2189T | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as rs751107576, COSV71591969; called by muse, mutect2, varscan2
- PCDHB3 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50572382; called by muse, mutect2
- PLCB4 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.324); catalogued as COSV53793075; called by muse, mutect2, varscan2
- ROS1 | c.6472G>A p.G2158S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63854995; called by muse, mutect2, varscan2
- RYR2 | c.12920G>A p.R4307H | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs769146715, COSV63684322, COSV63691311; called by muse, mutect2, varscan2
- SALL1 | c.2150G>C p.C717S | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV51757159; called by muse, mutect2, varscan2
- SDHC | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as CM166505, COSV61368177; called by muse, mutect2, varscan2
- SUSD4 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770364634, COSV59552729; called by muse, mutect2, varscan2
- TTN | c.18038A>G p.Q6013R (on ENST00000591111; = p.Q5086R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | PolyPhen benign (0); catalogued as COSV60043403; called by muse, mutect2, varscan2
- UNC5A | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as rs754389756, COSV52839778; called by muse, mutect2, varscan2
- VCPIP1 | c.545A>G p.K182R | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs147256539; called by muse, mutect2, varscan2
- CFAP47 | c.2838del p.A947Hfs*24 (on ENST00000378653 / NM_001304548.2; = p.A947Hfs*3 on NM_152632.4) | Frame Shift Del (DEL) | VAF 33/56 reads (59%) | called by mutect2, pindel, varscan2
- ARHGEF15 | c.369G>A p.P123= | Silent (SNP) | VAF 21/334 reads (6%) | catalogued as rs777771857, COSV62724653, COSV62725136; called by muse, mutect2
- CHST6 | c.216C>T p.P72= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs1567409810, COSV60000044; called by muse, mutect2, varscan2
- HTR2C | c.246G>A p.K82= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV52209922, COSV52226029; called by muse, mutect2, varscan2
- IL23R | c.1800C>T p.I600= | Silent (SNP) | VAF 66/139 reads (47%) | catalogued as rs757424102, COSV61373352, COSV61374981; called by muse, mutect2, varscan2
- OR1C1 | c.375G>A p.A125= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs1045359996, COSV101376298, COSV68715720; called by muse, mutect2, varscan2
- PKHD1L1 | c.1845T>A p.V615= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV65742657; called by muse, mutect2, varscan2
- SLITRK2 | c.2403C>T p.T801= | Silent (SNP) | VAF 8/186 reads (4%) | catalogued as rs1001861008, COSV59425262; called by muse, mutect2
- UNC13C | c.1149C>G p.T383= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV52870368; called by muse, mutect2, varscan2
- ZNF608 | c.1305G>T p.G435= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV60437519; called by muse, mutect2, varscan2
- CCNQP1 | n.65C>A | RNA (SNP) | VAF 87/227 reads (38%) | called by muse, mutect2, varscan2
- CYP11B1 | c.239+130G>A | Intron (SNP) | VAF 28/71 reads (39%) | catalogued as COSV52826980; called by muse, mutect2, varscan2
- HMGB1P1 | n.566A>C | RNA (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
